FM case AD10655 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas.
https://portal.gdc.cancer.gov/cases/8a3be9a8-4705-4f92-bca2-e2fe4d5d0d3f

Female, 70.4 years: Melanoma, NOS (ICD-O-3 8720/3); specimen biopsied or resected from the urethra. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
